Somatic mutation profile of tumor specimen TCGA-DJ-A13W-01A (aliquot TCGA-DJ-A13W-01A-11D-A10S-08) from TCGA case TCGA-DJ-A13W, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 45.3 years (16,558 days).
Specimen TCGA-DJ-A13W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb323916-e2d2-44a1-ae41-41d736942666.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13W-10A (Blood Derived Normal), aliquot TCGA-DJ-A13W-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/265adc11-89bf-470f-9773-510a62d44ca9

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1B | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53123986, COSV53152421; called by muse, mutect2, varscan2
- EPHB1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV67655144, COSV67655577; called by muse, mutect2
- KANK2 | c.1624G>A p.A542T (on ENST00000586659 / NM_001379562.1; = p.A550T on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV62010442; called by muse, mutect2, varscan2
- NAV3 | c.4019C>T p.T1340I | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV57116955; called by muse, mutect2
- OR2L3 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 140/327 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs202209437, COSV63455676; called by muse, mutect2, varscan2
- TNS1 | c.2933C>G p.T978R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50783899; called by muse, mutect2, varscan2
- TPH2 | c.942-2A>G p.X314_splice | Splice Site (SNP) | VAF 88/203 reads (43%) | catalogued as COSV61594813; called by muse, mutect2, varscan2
- ENGASE | c.*627C>A | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
